Somatic mutation profile of tumor specimen MBCProject_4424_T2_WES (aliquot MBCProject_4424_T2_WES_1) from CMI case MBCProject_4424, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_4424_T2_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Pleura; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a30560c-30a9-454b-b38c-2514376cff5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_4424_SALIVA (Saliva), aliquot MBCProject_4424_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23432a87-675a-4a5c-b71a-f7b15f73103a

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF4G3 | c.210G>A p.A70= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs867464911, COSV63573095; called by muse, varscan2
